FM case AD9509 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/5d32aaa0-d9ac-487c-b8ac-aa996259123c

Female, 43.0 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thymus; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
